Gene-level copy-number profile of tumor specimen TCGA-A2-A04U-01A from TCGA case TCGA-A2-A04U, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.8 years (17,474 days).
Specimen TCGA-A2-A04U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.544dd94e-abd8-4cca-98cf-d1c2c646f23a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A04U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b7743205-a577-4d54-b398-d97c83eaf78c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 14,471; copy number 2: 21,099; copy number 3: 13,398; copy number 4: 5,922; copy number 5: 2,442; copy number 6: 1,441; copy number 7: 491; copy number 8: 273; copy number 9: 150; copy number 10: 62; copy number 14: 5; copy number 15: 1; copy number 21: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A04U-01A-11D-A111-01): tumor purity 0.82, ploidy 2.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:51,158,282–51,283,896, 3 genes: SRSF10P1, MEX3C, RNU1-46P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,529 genes in 112 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:74,963,314–79,346,445, 74 genes, copy number 6 (broad region; genes not listed).
- chr1:105,927,620–109,709,551, 77 genes, copy number 5–9 (broad region; genes not listed).
- chr1:116,909,916–121,580,524, 106 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr1:151,402,724–153,567,890, 120 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:159,171,609–161,685,252, 134 genes, copy number 5 (broad region; genes not listed).
- chr1:179,025,804–181,238,604, 57 genes, copy number 6–7: FAM20B, AL139132.1, TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1, AXDND1, MEF2AP1, HNRNPA1P54, AL160286.3, NPHS2, RNU5F-2P, AL160286.1, AL160286.2, TDRD5, AL359853.2, FAM163A, AL359853.1, LINC02818, TOR1AIP2, AL353708.3, TOR1AIP1, RN7SL230P, AL353708.2, AL353708.1, CEP350, RPSAP16, AL590632.1, AL390718.1, QSOX1, LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA, XPR1, U6, LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3, STX6, MR1, IER5, LINC01732, AL358393.1, LINC01699.
- chr1:226,231,149–229,892,046, 135 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:234,527,887–239,974,245, 107 genes, copy number 5–10 (broad region; genes not listed).
- chr1:247,449,118–248,919,946, 85 genes, copy number 6 (broad region; genes not listed).
- chr2:59,647,621–63,087,322, 78 genes, copy number 7 (broad region; genes not listed).
- chr2:64,143,239–66,433,470, 53 genes, copy number 5 (within-gene range 3–5): AC012368.1, LINC00309, AC012368.3, AC114752.1, AC114752.2, MIR4433B, MIR4433A, RPL23AP37, LGALSL-DT, AC008074.1, LGALSL, LINC01805, AC008074.2, AFTPH, MIR4434, RNU6-100P, LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576, CEP68, RAB1A, SNORA74, AC007318.1, VDAC2P5, ACTR2, SPRED2, AC012370.1, AC007389.1, AC012370.2, DNAJB12P1, RPS15AP15, RN7SL635P, VTRNA2-2P, AC007389.2, AC007389.3, KRT18P33, AC007741.1, AC118345.1, AC092669.1, MIR4778, LINC01873, MEIS1-AS3.
- chr2:95,789,654–98,782,548, 85 genes, copy number 5 (broad region; genes not listed).
- chr2:157,257,705–160,877,850, 59 genes, copy number 5 (within-gene range 3–5): GALNT5, RN7SKP281, ERMN, FAM133DP, CYTIP, ACVR1C, AC019186.1, ACVR1, UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1, CCDC148, HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2, DAPL1, AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P, TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888, WDSUB1, BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2, PLA2R1, ITGB6, AC092153.1, LINC02478, RBMS1, MIR4785, AC096656.1, RN7SL423P.
- chr2:169,479,480–172,109,982, 52 genes, copy number 6–8: BBS5, AC093899.2, KLHL41, FASTKD1, AC093899.1, PPIG, CCDC173, AC016772.1, PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P, MYO3B, MYO3B-AS1, HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, AC010092.1, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT.
- chr3:9,779,860–11,771,350, 59 genes, copy number 6 (within-gene range 2–6): TADA3, ARPC4, ARPC4-TTLL3, TTLL3, AC022382.1, RPUSD3, CIDEC, JAGN1, IL17RE, IL17RC, RNU6-882P, AC018809.3, CRELD1, AC018809.1, PRRT3, PRRT3-AS1, AC018809.2, EMC3, EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2, TATDN2, AC022384.1, LINC00852, GHRL, GHRLOS, AC022384.2, SEC13, ATP2B2, MIR378B, MIR885, ATP2B2-IT1, ATP2B2-IT2, LINC00606, AC018495.1, SLC6A11, AC027128.1, SLC6A1, SLC6A1-AS1, AC066580.1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr3:145,523,538–150,630,445, 95 genes, copy number 5–7 (broad region; genes not listed).
- chr3:151,079,506–155,854,456, 78 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr4:121,131,408–126,017,357, 53 genes, copy number 5–7 (within-gene range 3–7): TNIP3, RNU6-948P, QRFPR, Y_RNA, AC093816.1, TUBB4BP5, ANXA5, TMEM155, PP12613, EXOSC9, CCNA2, BBS7, AC079341.1, TRPC3, AC097533.1, RN7SL335P, KIAA1109, ADAD1, IL2, IL21, IL21-AS1, AC053545.1, CETN4P, BBS12, AC021205.2, FGF2, AC021205.1, AC021205.3, NUDT6, SPATA5, AC026402.1, AC026402.2, SPRY1, AC093821.1, LINC02435, LINC01091, AC096732.1, RPL21P50, AC093767.1, AC108075.1, PPIAP76, AC121154.1, AC133530.1, TUBAP10, TECRP2, LINC02516, ANKRD50, FAT4, Y_RNA, MIR2054, AC104664.1, NUP58P1, TMEM248P1.
- chr6:25,261,239–26,659,752, 83 genes, copy number 5–6 (broad region; genes not listed).
- chr7:89,882,353–93,226,469, 56 genes, copy number 7 (within-gene range 3–7): STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2.
- chr8:16,598,758–20,551,405, 71 genes, copy number 5–8 (broad region; genes not listed).
- chr8:55,067,585–57,984,126, 51 genes, copy number 8: AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1.
- chr9:19,453,209–22,824,213, 76 genes, copy number 5–9 (broad region; genes not listed).
- chr9:123,736,437–125,967,377, 47 genes, copy number 6 (within-gene range 3–6): AL390774.2, AL390774.1, PIGFP2, LHX2, AC006450.3, AC006450.1, AC006450.2, NEK6, AL162724.2, AL162724.1, PSMB7, ADGRD2, NR5A1, AL354979.1, NR6A1, AL669818.1, RN7SL302P, MIR181A2HG, MIR181A2, MIR181B2, AL354928.1, OLFML2A, WDR38, RPL35, ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2, PPP6C, PRPS1P2, RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P, AL627223.1, Metazoa_SRP, AL359632.1, MAPKAP1, RN7SL30P, AL162584.1, HNRNPA1P15, AL358074.1, PBX3.
- chr10:12,068,954–14,462,142, 48 genes, copy number 5 (within-gene range 3–5): DHTKD1, RNU6-88P, SEC61A2, MIR548AK, NUDT5, CDC123, AL512770.1, RN7SL198P, CAMK1D, AL391314.1, RNU6ATAC39P, AL731559.1, MIR4480, MIR4481, MIR548Q, AL353586.1, CCDC3, RNA5SP300, RPL5P25, OPTN, SNRPGP5, AL355355.2, AL355355.1, BTBD7P1, RPL36AP36, MCM10, RNU6-6P, UCMA, PHYH, RBISP1, SEPHS1, AL355870.2, AL355870.1, BEND7, Y_RNA, AL590677.1, PRPF18, RPL6P24, AL157392.5, AL157392.3, FRMD4A, AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5, AC044781.1, AL157896.1.
- chr10:33,684,755–37,858,106, 62 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:45,374,176–47,619,480, 63 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:118,046,279–123,697,399, 100 genes, copy number 5–21 (within-gene range 3–21) (broad region; genes not listed).
- chr11:32,583,798–35,897,735, 68 genes, copy number 5–7 (broad region; genes not listed).
- chr11:48,216,810–49,810,419, 47 genes, copy number 9 (within-gene range 4–9): OR4B1, OR4B2P, OR4X2, OR4X1, OR4S1, OR4C3, OR4C4P, OR4C5, OR4C2P, OR4C10P, OR4C9P, OR4R1P, OR4A47, OR4A48P, OR4A46P, OR4A40P, OR4A43P, OR4A45P, OR4A41P, OR4A42P, OR4A44P, AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B, AC084851.4, TRIM64C, AC084851.3, AC084851.1, UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1, AC118942.1, TYRL, CBX3P8, AC135977.1, AC136759.1.
- chr12:10,069,554–11,895,377, 71 genes, copy number 5–8 (broad region; genes not listed).
- chr12:25,959,029–29,784,759, 74 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr18:23,134,564–25,352,190, 48 genes, copy number 6 (within-gene range 3–6): CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.
- chr18:68,102,087–74,598,885, 79 genes, copy number 5–6 (broad region; genes not listed).
- chr19:13,731,760–18,958,258, 299 genes, copy number 5 (broad region; genes not listed).
- chr20:28,563,850–31,845,604, 66 genes, copy number 5 (broad region; genes not listed).
- chr20:32,355,053–35,950,370, 133 genes, copy number 5–6 (broad region; genes not listed).
- chr20:45,629,739–47,656,877, 68 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr21:37,951,425–40,864,473, 59 genes, copy number 5–6: DSCR4, DSCR4-IT1, DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.3, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1, B3GALT5, B3GALT5-AS1, AF064860.1, AF064860.2, IGSF5, PCP4, DSCAM, MIR4760, DSCAM-AS1, AF064863.1, DSCAM-IT1, AF064866.1, YRDCP3.
- chr22:23,536,881–25,197,448, 81 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,469. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
